Somatic mutation profile of tumor specimen TCGA-FM-8000-01A (aliquot TCGA-FM-8000-01A-11D-2210-10) from TCGA case TCGA-FM-8000, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 70.4 years (25,724 days).
Specimen TCGA-FM-8000-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eca40925-d879-4df4-bd5f-5ff7875337af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FM-8000-10A (Blood Derived Normal), aliquot TCGA-FM-8000-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b8af9ad-22d7-437a-85eb-0644b1376d2e

The open-access MAF lists 162 somatic variants for this specimen: 117 protein-altering or splice-affecting, 42 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 42, Nonsense Mutation 9, Frame Shift Del 5, Splice Site 3, Intron 2, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.6392G>A p.R2131Q | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs122445101, CM960139, COSV100970861; ClinVar: pathogenic; called by muse, varscan2
- EZH2 | c.1922A>T p.Y641F (on ENST00000460911 / NM_001203247.2; = p.Y646F on NM_004456.5) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs267601394, COSV57445929, COSV57446008, COSV57446054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC024592.3 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); catalogued as rs1170869493; called by muse, mutect2, varscan2
- ADCY2 | c.3137C>T p.T1046M | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753213597; called by muse, mutect2, varscan2
- ADRA1D | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs890664407, COSV65240431; called by muse, mutect2, varscan2
- ARID1A | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 91/247 reads (37%) | catalogued as COSV61389661; called by muse, mutect2, varscan2
- AVL9 | c.1783G>A p.V595I | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs754333751; called by muse, mutect2, varscan2
- BCO2 | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs141269805; called by muse, mutect2, varscan2
- C14orf28 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.034); catalogued as rs771127672, COSV57333040; called by muse, mutect2, varscan2
- CCDC88C | c.4513G>A p.D1505N | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs767457119; called by muse, mutect2, varscan2
- CSMD1 | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.406); catalogued as rs562417147; called by muse, varscan2
- DAAM2 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs574596379, COSV99227639; called by muse, mutect2, varscan2
- DCC | c.2030A>G p.N677S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs1300419148; called by muse, mutect2, varscan2
- DLGAP2 | c.1112G>A p.W371* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV70097201; called by muse, varscan2
- DNAH3 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs145828896; called by muse, mutect2, varscan2
- DNER | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs373276946; called by muse, varscan2
- EGFR | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs770290445, COSV51843352; called by muse, mutect2, varscan2
- ERC2 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs201400364, COSV55631219; called by muse, mutect2, varscan2
- GJA9 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as rs769442681, COSV62532507; called by muse, mutect2, varscan2
- GNAI2 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553703235; called by muse, mutect2, varscan2
- GPR158 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs756509446, COSV66273993; called by muse, mutect2, varscan2
- IGLV1-44 | c.340A>G p.S114G | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs1455009385; called by muse, varscan2
- IGLV4-60 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as rs551017194; called by muse, varscan2
- IGLV5-45 | c.143A>C p.N48T | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs202076025; called by muse, varscan2
- IGLV7-43 | c.222C>G p.N74K | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs185685487; called by muse, varscan2
- KLHL6 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140971016, COSV58065163; called by muse, mutect2, varscan2
- KPRP | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 29/123 reads (24%) | catalogued as rs569937176; called by muse, mutect2, varscan2
- LOXL4 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766992310, COSV53256517; called by muse, mutect2, varscan2
- MAP4K5 | c.2123A>G p.N708S | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs780733834; called by muse, mutect2, varscan2
- MCM4 | c.646A>T p.K216* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | catalogued as rs1256399002; called by muse, mutect2, varscan2
- MEF2B | c.248A>C p.D83A | Missense Mutation (SNP) | VAF 64/90 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50761376, COSV50764249; called by muse, varscan2
- MYO7B | c.2001C>G p.D667E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV99066279; called by muse, mutect2, varscan2
- MZF1 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs756827802, COSV53040461; called by muse, mutect2, varscan2
- NLRP1 | c.2959C>T p.R987W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199748129, COSV52563658, COSV52572656; called by muse, mutect2, varscan2
- OR2L8 | c.755C>A p.A252E | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV61726105, COSV61728344; called by muse, mutect2, varscan2
- PABPN1 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs770139042, COSV53729221; called by muse, mutect2, varscan2
- PCYT1B | c.381G>T p.M127I | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV63266176; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.373); catalogued as rs1443158590; called by muse, mutect2
- PTBP2 | c.458G>A p.R153H (on ENST00000426398 / NM_001300986.2; = p.R145H on NM_021190.4) | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs747827924, COSV64624832, COSV64624909; called by muse, mutect2, varscan2
- RGS3 | c.1250G>A p.R417Q (on ENST00000350696 / NM_001282923.2; = p.R305Q on NM_017790.4) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs762952712; called by muse, mutect2, varscan2
- RMND5A | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.264); catalogued as rs1291336366; called by muse, varscan2
- RUFY2 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs764008644, COSV66251937; called by muse, mutect2, varscan2
- SATB2 | c.1262T>C p.F421S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53480398; called by muse, mutect2, varscan2
- SLC10A4 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56718199; called by muse, mutect2, varscan2
- TIRAP | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs199561634, COSV67023845; called by muse, mutect2, varscan2
- USP20 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1174709618; called by muse, varscan2
- VANGL1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs148341022, CM127311; ClinVar: benign; called by muse, mutect2, varscan2
- ZMIZ2 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777127750; called by muse, mutect2, varscan2
- ZNF485 | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as rs755356075, COSV62424179; called by muse, mutect2, varscan2
- ZNF608 | c.2039C>T p.T680M | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs186374145; called by muse, mutect2, varscan2
- ZNF675 | c.3+2T>G p.X1_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as rs1002558191; called by muse, mutect2, varscan2
- ABRA | c.192A>C p.K64N | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AKR1C8P | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK3 | c.2060A>G p.N687S | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ANKRD35 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ASIC3 | c.231T>G p.D77E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ASTN2 | c.2746T>C p.C916R (on ENST00000313400 / NM_001365069.1; = p.C865R on NM_014010.5) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AURKA | c.942C>G p.S314R | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BCL6 | c.1923C>A p.H641Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3169G>A p.V1057M | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CACNA1F | c.78G>A p.W26* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- CCDC88C | c.3638A>G p.H1213R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CCDC88C | c.3545C>A p.S1182* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- CHI3L1 | c.660T>A p.S220R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.933T>A p.N311K | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DAZAP1 | c.1215C>G p.Y405* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- DNAH1 | c.7072A>G p.M2358V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA7 | c.1397C>G p.P466R | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ETS1 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- EZH2 | c.1979A>G p.K660R (on ENST00000460911 / NM_001203247.2; = p.K665R on NM_004456.5) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EZH2 | c.1978A>G p.K660E (on ENST00000460911 / NM_001203247.2; = p.K665E on NM_004456.5) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAIM | c.112-2A>G p.X38_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- FAT4 | c.14707G>A p.G4903R | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- FRMD4B | c.2429C>T p.T810I | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRIA2 | c.1541A>C p.K514T | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- HAUS6 | c.2539A>C p.K847Q | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HCRTR2 | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HINT2 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- HIVEP3 | c.1597_1607del p.P533Sfs*24 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- IGLV11-55 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KMT2D | c.7803_7804del p.S2604Lfs*50 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- KSR2 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- L1CAM | c.3730T>C p.S1244P | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- MBNL2 | c.172_173dup p.G59Rfs*18 | Frame Shift Ins (INS) | VAF 37/104 reads (36%) | called by mutect2, pindel, varscan2
- MLLT1 | c.343A>T p.N115Y | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- MTMR8 | c.324T>A p.D108E | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC1 | c.3778G>T p.A1260S (on ENST00000611571 / NM_001371720.1; = p.A271S on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MUC17 | c.9302G>A p.S3101N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- MXRA5 | c.1684G>T p.E562* | Nonsense Mutation (SNP) | VAF 93/259 reads (36%) | called by muse, mutect2, varscan2
- NCKAP5 | c.1552A>G p.R518G | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRC5 | c.1922T>G p.F641C | Missense Mutation (SNP) | VAF 95/149 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NUDT6 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- OR10A5 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- OR4C16 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- PATE1 | c.56T>C p.L19S | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- PFN1 | c.359A>C p.H120P | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFN1 | c.358C>G p.H120D | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIGC | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD2L2 | c.200A>T p.D67V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PNLIPRP1 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRG4 | c.3128_3131del p.V1043Efs*12 | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- PRKDC | c.5915A>C p.E1972A | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- PRPF39 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- RELN | c.3511A>C p.M1171L | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.031); called by muse, varscan2
- REV3L | c.5423G>A p.G1808E | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFX3 | c.2033G>A p.S678N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- RMND5A | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, varscan2
- RSPO3 | c.634+2T>C p.X212_splice | Splice Site (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- SCN7A | c.1209_1210del p.R403Sfs*3 | Frame Shift Del (DEL) | VAF 38/127 reads (30%) | called by pindel, varscan2
- SIPA1L1 | c.4508G>A p.R1503K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- SLFN12 | c.1219A>C p.K407Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPCS1 | c.442del p.Q148Kfs*35 (on ENST00000233025; = p.Q81Kfs*35 on NM_014041.5) | Frame Shift Del (DEL) | VAF 54/199 reads (27%) | called by mutect2, pindel, varscan2
- UNKL | c.1642A>G p.S548G | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- USF1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- WAS | c.875A>T p.D292V | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- XPO1 | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 137/190 reads (72%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZNF559 | c.20C>G p.T7R | Missense Mutation (SNP) | VAF 92/112 reads (82%) | SIFT tolerated (0.2); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ABCA13 | c.5379T>A p.I1793= | Silent (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- ABLIM1 | c.423C>T p.N141= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs376120417; called by muse, mutect2, varscan2
- ADCY9 | c.3351G>A p.A1117= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs371159341; called by muse, mutect2, varscan2
- ATOH1 | c.900C>T p.S300= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs749567383, COSV60038270; called by muse, mutect2, varscan2
- ATP9A | c.486C>T p.I162= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs376498362, COSV58769468; called by muse, mutect2, varscan2
- BCL2 | c.456G>A p.E152= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as COSV61382975; called by muse, mutect2, varscan2
- COL6A3 | c.4767C>T p.D1589= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as rs1490710916; called by muse, mutect2, varscan2
- DSG2 | c.57C>T p.N19= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs587780925; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1167A>G p.E389= | Silent (SNP) | VAF 34/85 reads (40%) | called by muse, varscan2
- FAM102A | c.9C>T p.F3= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV66194678; called by muse, mutect2, varscan2
- FAM118B | c.174A>G p.Q58= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV100796810; called by muse, mutect2, varscan2
- H3C4 | c.267G>C p.A89= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as COSV61912174; called by muse, mutect2, varscan2
- HAUS6 | c.2400A>G p.K800= | Silent (SNP) | VAF 48/125 reads (38%) | called by muse, mutect2, varscan2
- HOXD4 | c.363G>A p.P121= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs769043641, COSV60460434; called by muse, mutect2
- IGF2R | c.864C>T p.C288= | Silent (SNP) | VAF 36/92 reads (39%) | called by muse, varscan2
- KIAA0408 | c.1206T>C p.H402= | Silent (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- KREMEN2 | c.36C>T p.L12= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as rs987259926; called by muse, mutect2, varscan2
- LTB | c.72A>G p.A24= | Silent (SNP) | VAF 55/147 reads (37%) | called by muse, mutect2, varscan2
- LVRN | c.687C>T p.G229= | Silent (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- MACROD2 | c.1119G>A p.S373= (on ENST00000642719; = p.S345= on NM_080676.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 46/114 reads (40%) | catalogued as rs748741601, COSV54018764, COSV99429734; called by muse, mutect2, varscan2
- MAG | c.999G>A p.G333= | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as rs1189865665; called by muse, mutect2, varscan2
- MDN1 | c.5364G>A p.L1788= | Silent (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1623C>T p.G541= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV56513205; called by muse, mutect2, varscan2
- PCDHGA1 | c.1674C>T p.N558= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV65295434, COSV65296327; called by muse, varscan2
- PDE1C | c.915T>G p.A305= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV58507238; called by muse, varscan2
- PLD2 | c.1258C>T p.L420= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as rs1473171424; called by muse, mutect2, varscan2
- PRPF40B | c.321C>T p.R107= (on ENST00000380281; = p.R101= on NM_012272.3) | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs771249704; called by muse, mutect2, varscan2
- PSMC1 | c.24T>C p.G8= | Silent (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- RBMX2 | c.330T>C p.D110= | Silent (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- RYR2 | c.7623C>T p.H2541= | Silent (SNP) | VAF 63/288 reads (22%) | catalogued as rs753435083, COSV100771088; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC16A | c.1038T>G p.R346= | Silent (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- SERPINB7 | c.795G>A p.R265= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1256064853; called by muse, mutect2
- SLC6A11 | c.1698G>A p.P566= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as rs138273152; called by muse, mutect2, varscan2
- SLC6A3 | c.1515C>T p.S505= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs114563841, COSV54362171, COSV54367714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPRED3 | c.339G>A p.L113= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as rs1304186860; called by muse, mutect2, varscan2
- TRIM42 | c.1137C>T p.G379= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as rs914390547; called by muse, mutect2, varscan2
- TSEN15 | c.75C>A p.G25= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs902856828; called by muse, mutect2, varscan2
- USP29 | c.486A>G p.L162= | Silent (SNP) | VAF 80/103 reads (78%) | catalogued as COSV54141332; called by muse, mutect2, varscan2
- VPS13B | c.7440C>T p.C2480= | Silent (SNP) | VAF 73/195 reads (37%) | catalogued as rs748588048, COSV62138351; called by muse, mutect2, varscan2
- ZNF319 | c.138C>A p.G46= | Silent (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- ZNF438 | c.1240A>C p.R414= | Silent (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- ZSCAN20 | c.1974C>T p.C658= | Silent (SNP) | VAF 70/159 reads (44%) | called by muse, mutect2, varscan2
- ILF3 | c.2059+893T>G | Intron (SNP) | VAF 72/89 reads (81%) | called by muse, mutect2, varscan2
- MAST2 | c.500+35036G>T | Intron (SNP) | VAF 59/122 reads (48%) | called by muse, mutect2, varscan2
- TMPO | chr12:98537574 T>C | 3'Flank (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
